Surgical pathology report (de-identified scan), TCGA case TCGA-19-5956, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5956-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A. LEFT FRONTOTEMPORAL BRAIN TUMOR, REMOVAL:
-- GLIOBLASTOMA MULTIFORME, GIANT CELL TYPE (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Clinical History:

Left GBM

Specimens Submitted As:

A: LEFT FRONTAL TEMPORAL BRAIN TUMOR

Gross Description:

Received fresh, post fixed in formalin, labeled with the patient's name and number, are multiple light tan irregular soft tissue fragments measuring 2.5 x 1.7 x 1.0 cm in aggregate. On section, the largest fragment is light tan. Submitted entirely in two cassettes.

Source: NCI Genomic Data Commons file 91f814e0-c583-4ff5-a779-0594dc651ed3 (TCGA-19-5956.D32E1293-485A-4B3C-A433-140750789471.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).